Somatic mutation profile of tumor specimen TCGA-06-0185-01A (aliquot TCGA-06-0185-01A-01D-1491-08) from TCGA case TCGA-06-0185, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 54.5 years (19,923 days).
Specimen TCGA-06-0185-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 528ad629-2a3b-4576-a44f-3924ac1891b6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0185-10B (Blood Derived Normal), aliquot TCGA-06-0185-10B-01D-1491-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/43253774-95e8-4967-983e-6c6500ea219b

The open-access MAF lists 63 somatic variants for this specimen: 48 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 14, Nonsense Mutation 4, RNA 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1907G>A p.G636D (on ENST00000288602 / NM_001374244.1; = p.G596D on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/231 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs397507483, CM060877, COSV56105584, COSV99951808; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACP7 | c.292C>T p.L98F | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58698366; called by muse, mutect2, varscan2
- AFDN | c.4891G>C p.E1631Q (on ENST00000447894 / NM_001366320.1; = p.E1629Q on NM_001040000.3) | Missense Mutation (SNP) | VAF 72/212 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); catalogued as COSV60038408; called by muse, varscan2
- AMOTL2 | c.1366G>A p.E456K | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs554840600, COSV51437856; called by mutect2, varscan2
- ARHGAP9 | c.208C>T p.P70S | Missense Mutation (SNP) | VAF 85/227 reads (37%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.999); catalogued as COSV62721422; called by muse, mutect2, varscan2
- ASGR2 | c.717C>A p.D239E | Missense Mutation (SNP) | VAF 52/626 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.088); catalogued as COSV54689547, COSV54690345; called by muse, mutect2
- ATXN1 | c.2116G>A p.V706I | Missense Mutation (SNP) | VAF 47/128 reads (37%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs199795863, COSV55209122; called by muse, mutect2, varscan2
- C9orf131 | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 62/269 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.33); catalogued as COSV56609793; called by muse, mutect2, varscan2
- C9orf131 | c.1359G>C p.W453C | Missense Mutation (SNP) | VAF 63/288 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as COSV56609799; called by muse, mutect2, varscan2
- CFAP20DC | c.1454G>A p.R485Q (on ENST00000482387 / NM_001351530.2; = p.R360Q on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 66/156 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.072); catalogued as rs571045260, COSV55916637; called by muse, mutect2, varscan2
- DDR2 | c.2444C>T p.P815L | Missense Mutation (SNP) | VAF 135/346 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.021); catalogued as COSV63369520; called by muse, mutect2, varscan2
- DSG3 | c.2939C>T p.T980M | Missense Mutation (SNP) | VAF 102/271 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as rs1353003026, COSV57124432; called by muse, mutect2, varscan2
- DYNC1I1 | c.448G>A p.V150M | Missense Mutation (SNP) | VAF 114/353 reads (32%) | SIFT tolerated (0.81); PolyPhen benign (0.044); catalogued as rs201114371, COSV61456326; called by muse, mutect2, varscan2
- EGFR | c.1951G>A p.V651M | Missense Mutation (SNP) | VAF 905/3728 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); catalogued as rs1562783502, COSV51774819; ClinVar: uncertain significance; called by mutect2, varscan2
- EPHB1 | c.2258A>G p.N753S | Missense Mutation (SNP) | VAF 111/241 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as COSV67654862; called by muse, mutect2, varscan2
- HMCN1 | c.4474A>T p.K1492* | Nonsense Mutation (SNP) | VAF 33/119 reads (28%) | catalogued as COSV54880137; called by muse, mutect2, varscan2
- HOOK1 | c.382G>A p.A128T | Missense Mutation (SNP) | VAF 65/148 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV64618107; called by muse, mutect2, varscan2
- HYDIN | c.826G>A p.V276M | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as rs754459784, COSV55478066; called by mutect2, varscan2
- JADE1 | c.448T>A p.W150R | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56904456; called by muse, mutect2, varscan2
- KATNA1 | c.1193T>G p.L398W | Missense Mutation (SNP) | VAF 6/109 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV59501715; called by muse, mutect2
- KIF19 | c.1462G>A p.D488N | Missense Mutation (SNP) | VAF 33/158 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.068); catalogued as rs765352519, COSV63428883; called by muse, mutect2, varscan2
- LBP | c.637C>T p.L213F | Missense Mutation (SNP) | VAF 104/362 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.861); catalogued as rs370114388, COSV54138738; called by muse, varscan2
- LRRC55 | c.226C>T p.R76C | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.912); catalogued as rs575568934, COSV73006334; called by muse, mutect2, varscan2
- MICB | c.680C>T p.A227V | Missense Mutation (SNP) | VAF 48/156 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52855546; called by muse, mutect2, varscan2
- MYH11 | c.4034G>A p.R1345Q | Missense Mutation (SNP) | VAF 120/352 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs150883363; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NLRP5 | c.2200C>T p.R734W | Missense Mutation (SNP) | VAF 139/523 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.158); catalogued as rs771396943, COSV66762329; called by muse, mutect2, varscan2
- NTN4 | c.490T>C p.C164R | Missense Mutation (SNP) | VAF 11/143 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59217994; called by muse, mutect2
- OR13F1 | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 18/276 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs191015152, COSV58251628; called by muse, mutect2
- PDZD3 | c.1490C>T p.T497I (on ENST00000531114; = p.T417I on NM_024791.4) | Missense Mutation (SNP) | VAF 15/198 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); catalogued as COSV52702335; called by muse, mutect2
- PKNOX1 | c.575C>T p.P192L | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.829); catalogued as rs981443475, COSV52334393; called by muse, mutect2, varscan2
- PLB1 | c.832G>A p.V278M | Missense Mutation (SNP) | VAF 45/130 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs778756062, COSV59819943; called by muse, mutect2, varscan2
- PRKCB | c.1891G>A p.D631N | Missense Mutation (SNP) | VAF 43/86 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1207487721, COSV57767885; called by muse, mutect2, varscan2
- RBMXL1 | c.980A>T p.Y327F | Missense Mutation (SNP) | VAF 161/359 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.3); catalogued as COSV53098855; called by muse, mutect2, varscan2
- RP1 | c.2783C>A p.T928N | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.174); catalogued as COSV55112446; called by muse, mutect2
- RUSC2 | c.1776C>A p.C592* | Nonsense Mutation (SNP) | VAF 40/83 reads (48%) | catalogued as COSV63427743; called by muse, mutect2, varscan2
- SEMG1 | c.565G>T p.G189* | Nonsense Mutation (SNP) | VAF 11/183 reads (6%) | catalogued as COSV54872115; called by muse, mutect2
- SLC6A13 | c.1091G>A p.R364Q | Missense Mutation (SNP) | VAF 60/134 reads (45%) | SIFT tolerated (0.31); PolyPhen benign (0.354); catalogued as rs1442103087, COSV58255510; called by muse, varscan2
- SNX15 | c.241C>T p.R81W | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs142024969, COSV57245715, COSV57245957; called by muse, mutect2, varscan2
- STAT1 | c.602A>T p.K201M | Missense Mutation (SNP) | VAF 71/241 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.489); catalogued as COSV61189675; called by muse, mutect2, varscan2
- TMTC1 | c.1058G>A p.R353Q (on ENST00000539277 / NM_001193451.2; = p.R245Q on NM_175861.3) | Missense Mutation (SNP) | VAF 76/157 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375595309; called by muse, mutect2, varscan2
- TP53BP1 | c.357-1G>C p.X119_splice | Splice Site (SNP) | VAF 29/158 reads (18%) | catalogued as COSV55497641; called by muse, mutect2, varscan2
- TRIM59 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 119/295 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.026); catalogued as COSV59086504; called by muse, mutect2, varscan2
- TRPC7 | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs754596685, COSV61453454; called by muse, mutect2, varscan2
- TTN | c.56176C>T p.R18726W (on ENST00000591111; = p.R11302W on NM_003319.4) | Missense Mutation (SNP) | VAF 69/185 reads (37%) | PolyPhen probably damaging (0.999); catalogued as rs727504479, COSV59935273; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UNC119B | c.454C>T p.R152W | Missense Mutation (SNP) | VAF 152/321 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1368666503, COSV60865813; called by muse, mutect2, varscan2
- ZNF26 | c.868G>A p.E290K | Missense Mutation (SNP) | VAF 9/115 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as rs1295379790; called by muse, mutect2
- ZNF831 | c.3649C>T p.R1217* | Nonsense Mutation (SNP) | VAF 26/83 reads (31%) | catalogued as rs376362684, COSV64037445; called by muse, mutect2, varscan2
- RAB11FIP5 | c.1202_1224del p.L401Pfs*3 | Frame Shift Del (DEL) | VAF 34/106 reads (32%) | called by mutect2, pindel, varscan2
- ABCA2 | c.1248C>T p.G416= (on ENST00000614293; = p.G386= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as rs770999419, COSV99688684; called by muse, varscan2
- ADAM9 | c.351G>A p.R117= | Silent (SNP) | VAF 93/249 reads (37%) | catalogued as COSV65946586; called by muse, mutect2, varscan2
- AFDN | c.4830G>C p.R1610= (on ENST00000447894 / NM_001366320.1; = p.R1608= on NM_001040000.3) | Silent (SNP) | VAF 28/77 reads (36%) | catalogued as COSV60038390; called by muse, varscan2
- COL6A3 | c.3201G>A p.V1067= | Silent (SNP) | VAF 14/109 reads (13%) | catalogued as COSV55082878; called by muse, mutect2, varscan2
- EXOSC3 | c.6C>A p.A2= | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as rs752749069, COSV59203454, COSV59204804; called by muse, mutect2, varscan2
- FBLN2 | c.3333C>A p.A1111= | Silent (SNP) | VAF 8/77 reads (10%) | catalogued as COSV55481831, COSV55489026; called by muse, mutect2, varscan2
- HSPB2 | c.471C>T p.V157= | Silent (SNP) | VAF 15/93 reads (16%) | catalogued as COSV57051411; called by muse, mutect2, varscan2
- OTUD3 | c.711G>A p.Q237= | Silent (SNP) | VAF 11/181 reads (6%) | called by muse, mutect2
- SEPTIN14 | c.981A>T p.P327= | Silent (SNP) | VAF 67/215 reads (31%) | catalogued as COSV66426326; called by muse, mutect2, varscan2
- SMG7 | c.1650C>T p.N550= | Silent (SNP) | VAF 12/222 reads (5%) | catalogued as COSV61630180; called by muse, mutect2
- UNC5A | c.1455G>A p.P485= | Silent (SNP) | VAF 33/105 reads (31%) | catalogued as rs779076146, COSV52837167; called by muse, mutect2, varscan2
- USH2A | c.3696G>A p.L1232= | Silent (SNP) | VAF 52/126 reads (41%) | catalogued as COSV56332402; called by muse, mutect2, varscan2
- ZBTB7C | c.27T>C p.I9= | Silent (SNP) | VAF 32/98 reads (33%) | catalogued as COSV59687763; called by muse, mutect2, varscan2
- ZSCAN10 | c.735G>A p.P245= (on ENST00000252463; = p.P300= on NM_032805.3) | Silent (SNP) | VAF 68/144 reads (47%) | catalogued as COSV52966951, COSV99373853; called by muse, mutect2, varscan2
- OR2W5 | n.639C>T | RNA (SNP) | VAF 12/178 reads (7%) | called by muse, mutect2
